Somatic mutation profile of tumor specimen 0DZB1S from CCDI case PBCTTK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.6 years (5,316 days).
Specimen 0DZB1S: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be637449-bc73-400b-bea5-1f530e9f29d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DZB1J (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b7600bc-a3da-40c6-bdb0-572e862ceae2

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 2, Silent 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPN1 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 51/552 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs149401779; called by muse, mutect2
- IL1RN | c.68C>T p.T23M (on ENST00000409930 / NM_173842.3; = p.T5M on NM_000577.5) | Missense Mutation (SNP) | VAF 49/498 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs55860727, COSV99381474; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOTCH1 | c.4587-1G>A p.X1529_splice | Splice Site (SNP) | VAF 40/544 reads (7%) | catalogued as COSV53085592; called by muse, mutect2
- BTN1A1 | c.519C>T p.P173= | Silent (SNP) | VAF 15/311 reads (5%) | called by muse, mutect2
- C8orf89 | c.264C>T p.A88= | Silent (SNP) | VAF 34/279 reads (12%) | catalogued as rs760532989; called by muse, mutect2, varscan2
